Somatic mutation profile of tumor specimen ALCH-AD6V-TTP1-A (aliquot ALCH-AD6V-TTP1-A-1-0-D-A502-36) from ALCHEMIST case ALCH-AD6V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.4 years (26,094 days).
Specimen ALCH-AD6V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66036fa8-f4aa-4909-978e-608a77285e8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AD6V-NB1-A (Blood Derived Normal), aliquot ALCH-AD6V-NB1-A-1-0-D-A502-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/443adc81-f3fe-4911-ad9e-1604850a3cd3

The open-access MAF lists 127 somatic variants for this specimen: 90 protein-altering or splice-affecting, 25 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 25, Intron 6, Splice Region 5, Nonsense Mutation 4, 3'UTR 3, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 2, 5'Flank 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 379/1138 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.706T>G p.Y236D | Missense Mutation (SNP) | VAF 283/658 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782289, CM1411658, COSV52672888, COSV52675514, COSV52783032; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL5 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs753752128; called by muse, mutect2
- ATP10B | c.2930G>A p.R977H | Missense Mutation (SNP) | VAF 55/829 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.322); catalogued as rs375571186; called by muse, mutect2
- C8A | c.1495T>C p.C499R | Missense Mutation (SNP) | VAF 46/1436 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332177228; called by muse, mutect2
- CD163L1 | c.2235C>A p.F745L | Missense Mutation (SNP) | VAF 26/816 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.289); catalogued as COSV58022448; called by muse, mutect2
- CES2 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV57696431; called by muse, mutect2, varscan2
- COL26A1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 88/552 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746391883, COSV58125966; called by muse, mutect2, varscan2
- CSN1S1 | c.85-2A>G p.X29_splice | Splice Site (SNP) | VAF 10/75 reads (13%) | catalogued as rs767072433; called by muse, mutect2, varscan2
- CSTF2 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 34/390 reads (9%) | catalogued as COSV63376367; called by muse, mutect2
- CUBN | c.489+5G>A | Splice Region (SNP) | VAF 34/376 reads (9%) | catalogued as COSV64701783; called by muse, mutect2
- DNAJB7 | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV99343984; called by muse, mutect2, varscan2
- DNHD1 | c.2872G>A p.G958S | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as rs546249355; called by muse, mutect2
- EMX2 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as rs1243726908, COSV71294466; called by muse, mutect2, varscan2
- FLNC | c.3967G>A p.V1323M | Missense Mutation (SNP) | VAF 67/667 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.042); catalogued as rs771676134; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR108 | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs530425574; called by muse, mutect2, varscan2
- HELZ | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 62/621 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104423471; called by muse, varscan2
- HMCN2 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1374023059, COSV101306964; called by muse, mutect2
- HRNR | c.1032G>C p.Q344H | Missense Mutation (SNP) | VAF 15/435 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as rs1408220024; called by muse, mutect2
- HTR3E | c.1115C>T p.P372L (on ENST00000415389 / NM_001256613.1; = p.P387L on NM_182589.2) | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs763844964, COSV58945882; called by muse, mutect2
- KRTAP19-7 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.086); catalogued as COSV58366279; called by muse, mutect2
- KRTAP7-1 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 67/728 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); catalogued as rs1476335480; called by muse, mutect2
- LMTK2 | c.2527A>T p.T843S | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs781342931; called by muse, mutect2
- LRRC14B | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV52053196; called by muse, mutect2, varscan2
- MARCHF11 | c.1148A>G p.H383R | Missense Mutation (SNP) | VAF 21/347 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs959278687; called by muse, mutect2
- MMRN1 | c.3610C>T p.R1204* | Nonsense Mutation (SNP) | VAF 14/114 reads (12%) | catalogued as rs972654070; called by muse, mutect2, varscan2
- MUC17 | c.3571G>T p.V1191L | Missense Mutation (SNP) | VAF 59/722 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs761230035; called by muse, mutect2
- NAA60 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 82/381 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1382156901, COSV62654306; called by muse, mutect2, varscan2
- NECAB2 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs753066050, COSV59419316; called by muse, mutect2
- NRROS | c.1507C>T p.L503F | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as COSV60746691; called by muse, mutect2
- PCDHA11 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 44/701 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1562644426; called by muse, mutect2
- PCDHA11 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV100246847; called by muse, mutect2
- PHF24 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs569076088, COSV99646151; called by muse, mutect2, varscan2
- PLCB1 | c.3175G>T p.E1059* | Nonsense Mutation (SNP) | VAF 14/142 reads (10%) | catalogued as COSV100570452; called by muse, mutect2
- RC3H1 | c.2861A>G p.H954R | Missense Mutation (SNP) | VAF 41/397 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); catalogued as rs1303300886; called by muse, mutect2, varscan2
- SLC12A7 | c.864C>G p.I288M | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866998518; called by muse, mutect2, varscan2
- SLC24A2 | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.267); catalogued as rs770762155; called by muse, mutect2, varscan2
- TCEAL4 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 43/798 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV101010279; called by muse, mutect2
- VCAN | c.5809G>C p.D1937H | Missense Mutation (SNP) | VAF 42/856 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs756870122, COSV54111792; called by muse, mutect2
- ZNF521 | c.1100G>T p.S367I | Missense Mutation (SNP) | VAF 156/431 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as rs781506159; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 140/389 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASIC5 | c.247C>A p.R83S | Missense Mutation (SNP) | VAF 169/914 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ATP1A3 | c.2405C>T p.P802L (on ENST00000545399 / NM_001256214.2; = p.P789L on NM_152296.5) | Missense Mutation (SNP) | VAF 70/372 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTG3 | c.647A>C p.Q216P | Missense Mutation (SNP) | VAF 96/378 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- C8orf33 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 210/890 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- CELA2A | c.4A>G p.I2V | Missense Mutation (SNP) | VAF 23/341 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2
- CENPF | c.2773_2776del p.A925Rfs*5 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by pindel, varscan2
- CLCN4 | c.1895A>T p.N632I | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- COL20A1 | c.1640C>A p.A547D | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- DES | c.1284C>G p.F428L | Missense Mutation (SNP) | VAF 22/585 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- DNAJC24 | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 11/265 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ELOVL4 | c.152G>T p.S51I | Missense Mutation (SNP) | VAF 68/321 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ENOX2 | c.1701G>A p.K567= (on ENST00000338144 / NM_001382520.1; = p.K538= on NM_006375.3 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 47/332 reads (14%) | called by muse, mutect2, varscan2
- FLG | c.4682A>G p.H1561R | Missense Mutation (SNP) | VAF 51/1030 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2
- FREM3 | c.4771C>T p.R1591C | Missense Mutation (SNP) | VAF 41/355 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- HCCS | c.-42G>T | Splice Region (SNP) | VAF 23/557 reads (4%) | called by muse, mutect2
- HIVEP1 | c.3733C>T p.R1245* | Nonsense Mutation (SNP) | VAF 14/390 reads (4%) | called by muse, mutect2
- IRS4 | c.2456C>A p.P819H | Missense Mutation (SNP) | VAF 78/699 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- KIR3DL3 | c.544A>T p.M182L | Missense Mutation (SNP) | VAF 73/380 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMC2 | c.3236C>A p.T1079K | Missense Mutation (SNP) | VAF 152/1393 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEB6 | c.998C>A p.T333N | Missense Mutation (SNP) | VAF 59/726 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MMP27 | c.1269C>G p.I423M | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPL38 | c.157_174del p.S53_R58del | In Frame Del (DEL) | VAF 17/204 reads (8%) | called by mutect2, pindel
- MYO5B | c.4792del p.S1598Pfs*19 | Frame Shift Del (DEL) | VAF 137/1244 reads (11%) | called by mutect2, pindel, varscan2
- OR10G4 | c.189C>A p.N63K | Missense Mutation (SNP) | VAF 26/550 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); called by muse, mutect2
- OR10Z1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 39/435 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.014); called by muse, mutect2
- PABPC4L | c.333C>G p.N111K | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2
- PBX2 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 68/546 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB1 | c.1908dup p.M637Hfs*46 | Frame Shift Ins (INS) | VAF 207/698 reads (30%) | called by mutect2, pindel, varscan2
- PLCXD3 | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLK3 | c.1619A>C p.E540A | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2
- PNPLA7 | c.804C>T p.I268= | Splice Region (SNP) | VAF 20/72 reads (28%) | called by muse, varscan2
- QSER1 | c.4697T>A p.M1566K (on ENST00000399302; = p.M1695K on NM_001076786.3) | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- RBMXL3 | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2
- RYR3 | c.3572G>A p.C1191Y | Missense Mutation (SNP) | VAF 140/558 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SAMSN1 | c.274A>C p.S92R | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.577); called by muse, mutect2
- SGIP1 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 77/639 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SH3PXD2A | c.428-1G>A p.X143_splice | Splice Site (SNP) | VAF 51/280 reads (18%) | called by muse, mutect2, varscan2
- SULF2 | c.2315G>A p.C772Y | Missense Mutation (SNP) | VAF 22/698 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNR | c.1104G>T p.Q368H | Missense Mutation (SNP) | VAF 42/887 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, mutect2
- TRIM27 | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 32/662 reads (5%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.937); called by muse, mutect2
- TTC37 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 55/434 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTN | c.20652A>G p.I6884M (on ENST00000591111; = p.I5957M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/221 reads (5%) | PolyPhen benign (0.046); called by muse, mutect2
- TXNRD1 | c.1647dup p.E550* (on ENST00000525566 / NM_001093771.3; = p.E452* on NM_003330.4) | Frame Shift Ins (INS) | VAF 32/153 reads (21%) | called by mutect2, pindel, varscan2
- ULK1 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- USH2A | c.2762T>A p.L921Q | Missense Mutation (SNP) | VAF 36/355 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- XYLB | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 23/578 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); called by muse, mutect2
- YY1AP1 | c.609T>A p.L203= (on ENST00000295566 / NM_139118.2; = p.L126= on NM_018253.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 63/650 reads (10%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 55/386 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF230 | c.1154T>G p.V385G | Missense Mutation (SNP) | VAF 41/501 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2
- ASB5 | c.489G>A p.Q163= | Silent (SNP) | VAF 17/369 reads (5%) | catalogued as rs997207364, COSV99641587; called by muse, mutect2
- ATCAY | c.465G>C p.R155= | Silent (SNP) | VAF 46/241 reads (19%) | called by muse, mutect2, varscan2
- CLCA1 | c.327T>C p.S109= | Silent (SNP) | VAF 12/243 reads (5%) | called by muse, mutect2
- COX10 | c.321A>G p.L107= | Silent (SNP) | VAF 27/808 reads (3%) | catalogued as rs1405019605, COSV55407179; called by muse, mutect2
- DCHS1 | c.7980A>G p.R2660= | Silent (SNP) | VAF 52/666 reads (8%) | catalogued as rs749078667; called by muse, mutect2
- DDX17 | c.2043G>A p.G681= | Silent (SNP) | VAF 23/865 reads (3%) | called by muse, mutect2
- DENND1B | c.2073T>G p.P691= | Silent (SNP) | VAF 60/499 reads (12%) | catalogued as COSV54152130; called by muse, mutect2, varscan2
- DOP1B | c.4329G>A p.K1443= | Silent (SNP) | VAF 63/203 reads (31%) | called by muse, mutect2, varscan2
- EGFR | c.2574G>T p.L858= | Silent (SNP) | VAF 381/1136 reads (34%) | catalogued as rs397517129, COSV51848696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM71D | c.435T>C p.S145= | Silent (SNP) | VAF 28/807 reads (3%) | called by muse, mutect2
- KRT1 | c.1575C>T p.Y525= | Silent (SNP) | VAF 84/507 reads (17%) | catalogued as rs780981259; called by muse, mutect2, varscan2
- NCAPG | c.909C>T p.A303= | Silent (SNP) | VAF 46/345 reads (13%) | catalogued as rs1185883214; called by muse, mutect2, varscan2
- NECAP1 | c.351C>T p.F117= | Silent (SNP) | VAF 80/617 reads (13%) | catalogued as rs1316512759, COSV60250088; called by muse, mutect2, varscan2
- NEIL3 | c.1791A>T p.P597= | Silent (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- OR10Q1 | c.813C>A p.T271= | Silent (SNP) | VAF 61/384 reads (16%) | called by muse, mutect2, varscan2
- OR2T4 | c.54G>A p.L18= | Silent (SNP) | VAF 47/986 reads (5%) | called by muse, mutect2
- OR4K14 | c.300T>A p.A100= | Silent (SNP) | VAF 48/631 reads (8%) | called by muse, mutect2
- PDGFRA | c.21G>A p.A7= | Silent (SNP) | VAF 57/1409 reads (4%) | catalogued as rs200090515, COSV99955876; ClinVar: likely benign; called by muse, mutect2
- PDXDC1 | c.525C>T p.V175= | Silent (SNP) | VAF 24/498 reads (5%) | called by muse, mutect2
- RGPD3 | c.3817T>C p.L1273= | Silent (SNP) | VAF 222/1174 reads (19%) | catalogued as rs758783973; called by muse, mutect2, varscan2
- TAF8 | c.621C>T p.D207= | Silent (SNP) | VAF 39/626 reads (6%) | catalogued as rs768530081; called by muse, mutect2
- TRIM51GP | c.192C>G p.L64= | Silent (SNP) | VAF 22/759 reads (3%) | called by muse, mutect2
- UNC13A | c.4437C>T p.G1479= | Silent (SNP) | VAF 56/281 reads (20%) | catalogued as rs778169618; called by muse, mutect2, varscan2
- WT1 | c.1438C>A p.R480= | Silent (SNP) | VAF 36/1254 reads (3%) | catalogued as COSV60070600; called by muse, mutect2
- ZNF837 | c.1395C>T p.H465= | Silent (SNP) | VAF 29/190 reads (15%) | called by muse, mutect2, varscan2
- DDC | c.315+12G>T | Intron (SNP) | VAF 22/722 reads (3%) | called by muse, mutect2
- GRIN2A | c.2357-38C>G | Intron (SNP) | VAF 36/708 reads (5%) | called by muse, mutect2
- LRP1 | c.10594+17C>T | Intron (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- MIR7-3 | chr19:4769652 T>C | 5'Flank (SNP) | VAF 56/373 reads (15%) | called by muse, mutect2, varscan2
- NAP1L4 | c.-18+1081C>T | Intron (SNP) | VAF 12/272 reads (4%) | catalogued as rs753395827; called by muse, mutect2
- OGFR | c.*21G>T | 3'UTR (SNP) | VAF 24/78 reads (31%) | catalogued as rs557376291; called by muse, varscan2
- P2RX7 | c.294+293G>A | Intron (SNP) | VAF 20/666 reads (3%) | called by muse, mutect2
- PPP1R1B | chr17:39622141 C>T | 5'Flank (SNP) | VAF 21/695 reads (3%) | called by muse, mutect2
- PRR29 | c.*113C>T | 3'UTR (SNP) | VAF 24/828 reads (3%) | catalogued as rs1026103130; called by muse, mutect2
- PTGIS | c.*45C>T | 3'UTR (SNP) | VAF 24/440 reads (5%) | called by muse, mutect2
- RMDN1 | c.729+17T>C | Intron (SNP) | VAF 40/138 reads (29%) | catalogued as rs764719202; called by muse, mutect2, varscan2
- SLC25A51P4 | n.716C>T | RNA (SNP) | VAF 113/784 reads (14%) | called by muse, mutect2, varscan2
